Gene-level copy-number profile of tumor specimen TCGA-QR-A6ZZ-01A from TCGA case TCGA-QR-A6ZZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 30.3 years (11,075 days).
Specimen TCGA-QR-A6ZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.7fe6dad7-b282-42c6-b99b-80fe5c96e41f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A6ZZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS.
https://portal.gdc.cancer.gov/files/ca2c3bfd-2100-41ef-b355-b6e36231f10d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 4,372; copy number 2: 52,004; copy number 3: 2,531; copy number 4: 863.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,716,327–158,743,415, 3 genes: OR6K3, OR6K4P, OR6K5P.
- chr2:168,915,498–169,031,324, 1 gene (within-gene range 0–2): ABCB11.
- chr3:11,745–54,346, 2 genes: LINC01986, AC066595.1.
- chr3:97,759,523–98,222,966, 20 genes: AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1, GABRR3, OR5BM1P, OR5AC1, OR5AC2, AC117460.1, OR5AC4P, POU5F1P7, OR5H1, OR5H14, OR5H15, OR5H5P, OR5H3P, OR5H4P.
- chr3:105,366,909–105,576,900, 1 gene (within-gene range 0–1): ALCAM.
- chr5:53,297,872–53,326,565, 1 gene (within-gene range 0–2): AC027329.1.
- chr5:125,966,777–125,968,085, 1 gene: RPSAP37.
- chr6:51,385,282–51,385,849, 1 gene: AL158050.2.
- chr7:78,486,530–78,487,028, 1 gene: AC007237.1.
- chr8:139,108,430–139,127,953, 2 genes: AC100807.1, AC100807.2.
- chr9:80,563,571–80,565,962, 2 genes: MTCO1P51, MTND2P9.
- chr11:5,856,674–5,902,730, 4 genes (within-gene range 0–1): OR52E8, OR52E7P, OR52E4, OR52E5.
- chr11:91,794,319–91,872,086, 1 gene (within-gene range 0–2): LINC02756.
- chr14:21,887,857–21,924,651, 5 genes: TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4.
- chr16:52,198,012–52,227,956, 1 gene (within-gene range 0–2): AC007333.2.
- chr19:27,638,483–27,794,005, 3 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,358. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
